Gene-level copy-number profile of tumor specimen C3L-00090-01 from CPTAC case C3L-00090, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.5 years (27,587 days).
Specimen C3L-00090-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8b7ceb99-7d17-4464-bd0e-ef236dae9f6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00090-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/1862e6bf-7a14-4626-af2b-dc5de3c8fb2e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 144; copy number 2: 53,367; copy number 3: 4,837; copy number 4: 29.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:27,919,376–29,168,333, 26 genes (within-gene range 0–2): TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739, RN7SL162P, CHEK2, HSCB, CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1.
- chr22:29,191,697–29,191,808, 1 gene (within-gene range 0–2): RNU6-1219P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 144. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
